Somatic mutation profile of tumor specimen TARGET-30-PAPTJB-01A (aliquot TARGET-30-PAPTJB-01A-01D) from TARGET case TARGET-30-PAPTJB, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 5.5 years (1,991 days).
Specimen TARGET-30-PAPTJB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4571c520-2e18-412e-bc98-be9ef5a08595.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPTJB-14A (Bone Marrow Normal), aliquot TARGET-30-PAPTJB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/295979c9-9848-415e-a753-c76ce82f04b3

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Nonsense Mutation 3, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1C | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54644212; called by muse, mutect2, varscan2
- ANKMY2 | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs1235149163, COSV61011141; called by muse, mutect2, varscan2
- ASB4 | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as COSV57943375, COSV57949069; called by muse, mutect2, varscan2
- FLT4 | c.3965C>A p.P1322H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV56100605; called by muse, mutect2, varscan2
- GIMAP6 | c.115A>T p.R39W | Missense Mutation (SNP) | VAF 94/520 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV61032651; called by muse, mutect2, varscan2
- IL21R | c.1376G>T p.W459L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61968874; called by muse, mutect2, varscan2
- KLK5 | c.435C>A p.Y145* | Nonsense Mutation (SNP) | VAF 21/110 reads (19%) | catalogued as COSV60449690; called by muse, mutect2, varscan2
- MEGF8 | c.1696A>G p.T566A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.035); catalogued as rs1012606989, COSV52076988; called by muse, mutect2, varscan2
- METRN | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV54797739; called by muse, mutect2, varscan2
- MUC5B | c.4596G>T p.K1532N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as COSV71590400, COSV71592171; called by mutect2, varscan2
- OR5T3 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs201540884, COSV57379593; called by muse, mutect2, varscan2
- OR6B3 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60113010; called by muse, mutect2, varscan2
- PALLD | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54974530; called by muse, mutect2, varscan2
- PEX6 | c.1438G>T p.V480F | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV55102023; called by muse, mutect2, varscan2
- PIKFYVE | c.4607G>T p.S1536I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV52237845; called by muse, mutect2, varscan2
- PKHD1 | c.1758C>A p.F586L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs777015620, COSV61863536; called by muse, mutect2, varscan2
- PROM2 | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58296952; called by muse, mutect2, varscan2
- PRUNE2 | c.1148C>A p.S383Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65038468; called by mutect2, varscan2
- RAB5B | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV64364670, COSV64364828; called by muse, mutect2, varscan2
- SLC25A41 | c.944C>A p.T315N | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV58599279; called by muse, mutect2, varscan2
- SLC6A5 | c.1395+1del | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as COSV54226416; called by mutect2, pindel, varscan2
- SPTBN1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63335914; called by muse, mutect2, varscan2
- TSHZ2 | c.2626G>T p.D876Y | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61587272, COSV61589931; called by muse, mutect2, varscan2
- USH2A | c.12490C>T p.H4164Y | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.097); catalogued as CD104125, COSV56335169; called by muse, mutect2, varscan2
- USP6 | c.3793G>T p.A1265S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.079); catalogued as COSV51476292; called by muse, mutect2, varscan2
- XIRP1 | c.4354G>T p.G1452C | Missense Mutation (SNP) | VAF 52/86 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV61137288; called by muse, mutect2, varscan2
- ZNF28 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 76/276 reads (28%) | catalogued as rs766915729, COSV60421981, COSV60422029; called by muse, mutect2, varscan2
- ZNF621 | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV59457502; called by muse, mutect2, varscan2
- EDRF1 | c.672C>T p.S224= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as rs758234773, COSV61762632; called by muse, mutect2, varscan2
- ELOA2 | c.432G>T p.P144= | Silent (SNP) | VAF 18/177 reads (10%) | catalogued as COSV55292990, COSV99796874; called by muse, mutect2, varscan2
- FASTKD1 | c.31T>C p.L11= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs759744604, COSV70006666; called by muse, mutect2, varscan2
- MOCOS | c.1956C>A p.A652= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs769549080, COSV54341471; called by muse, mutect2, varscan2
- MUC4 | c.57C>A p.L19= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100638942, COSV62135286; called by muse, mutect2, varscan2
- NPC2 | c.228C>A p.G76= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV53143040; called by muse, mutect2, varscan2
- SLC24A3 | c.147T>C p.L49= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV60113441; called by muse, mutect2, varscan2
- ZNF99 | c.*93G>T | 3'UTR (SNP) | VAF 20/66 reads (30%) | catalogued as COSV68054995; called by muse, mutect2, varscan2
